Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0T7, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0T7-01A (Primary Tumor).

[page 1 of 3]
Specimen: (

Received:

Spec Type: SURGICAL P

Status:

Subm Dr:

RIGHT BREAST CANCER INVASIVE

1CA-0-3

Carcinoma, infiltrating ductal, NOS 8500/3

Site: breast, NOS C50.9

1/27/11 *lu*

DATE: 1

DOCTOR(S): BILATERAL SIMPLE MASTECTOMY-SENTINEL NODE BX

- A. LT BREAST MASTECTOMY
- B. RT BREAST SENTINEL NODE #1
- C. RT BREAST SENTINEL NODE #2
- D. RT BREAST MASTECTOMY

RECEIVED IN FOUR PARTS.

PART A: RECEIVED FRESH LABELED LEFT BREAST MASTECTOMY, STITCH AT 1200 IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 15 X 14.5 X 4 CM IN GREATEST DIMENSIONS. THE NIPPLE IS UNREMARKABLE WITHIN A 6.3 X 3.6 CM SKIN ELLIPSE. THE SUPERFICIAL MARGIN IS MARKED BLUE WHILE THE DEEP ASPECT IS MARKED WITH BLACK INK. SECTIONING REVEALS CENTRAL FIBROSIS WITH MULTIPLE CYSTIC AREAS CONTAINING GREY MUCINOUS FLUID. THIS AREA IS MEASURES 10.5 X 9 X 3 CM AND IS SURROUNDED BY GROSSLY UNREMARKABLE YELLOW FATTY TISSUE. REPRESENTATIVE SECTIONS ARE SUBMITTED AS FOLLOWS: A1-NIPPLE; A2-CENTRAL DEEP MARGIN; A3-4 UPPER OUTER QUADRANT; A5-6 UPPER INNER QUADRANT; A7-8 LOWER INNER QUADRANT AND A9-10-LOWER OUTER QUADRANT.

PART B: RECEIVED FRESH LABELED SENTINEL NODE #1 HOT AND BLUE IS AN OVOID FRAGMENT OF BLUE COLORED TISSUE AND SURROUNDING YELLOW FAT MEASURING 2 X 1 X 1 CM. SECTIONING REVEALS A GROSSLY UNREMARKABLE BLUE DYED NODE MEASURING 1.7 CM IN GREATEST DIMENSION. A PORTION IS TAKEN PER PROTOCOL AND THE REMAINDER IS SUBMITTED LABELED B.

PART C: RECEIVED FRESH LABELED SENTINEL NODE #2 HOT IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 2 X 1 X 1 CM. SECTIONING REVEALS UNREMARKABLE NODAL TISSUE SUBMITTED ENTIRELY LABELED C.

PART D: RECEIVED FRESH LABELED [REDACTED] RIGHT BREAST MASTECTOMY, STITCH AT 12 O'CLOCK IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 17 X 15 X 5.0 CM. THE NIPPLE IS GROSSLY UNREMARKABLE WITHIN A 6 X 3 CM SKIN ELLIPSE. THE SUPERFICIAL ASPECT IS MARKED IN BLUE INK. THE DEEP MARGIN IS MARKED IN BLACK INK. SECTIONING REVEALS A FIRM FIBROUS NODULE IN THE UPPER INNER QUADRANT MEASURING 2.5 X 1.5 X 1.5 CM. THE LESION GROSSLY EXTENDS TO WITHIN 0.8 CM OF THE MOST MEDIAL MARGIN AND IS 0.7 CM FROM BOTH THE SUPERFICIAL AND DEEP MARGINS. THE CENTRAL PORTION OF THE BREAST CONSISTS OF DENSE FIBROUS TISSUE WITH NUMEROUS CYSTIC AREAS AND THIS SURROUNDED BY BLAND YELLOW FATTY TISSUE. THE CENTRAL AREA MEASURES 13 X 10.5 X 3.0 CM.

[page 2 of 3]
Patient: [REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED]

Status: [REDACTED]

Spec Type: SURGICAL P
(Continued)

Subm Dr: [REDACTED]

ADDITIONALLY LOOSE WITHIN THE CONTAINER ARE TWO FRAGMENTS OF GROSSLY UNREMARKABLE FATTY TISSUE TOGETHER MEASURING 7.5 X 5.7 X 2.0 CM. NO SECTIONS ARE SUBMITTED. D1--NIPPLE AND ADJACENT SKIN (MIRROR IMAGE TO RESEARCH), D2-3--FULL CROSS SECTION OF LESIONAL AREA, D4-5--FULL CROSS SECTION TO LESIONAL AREA. NOTE D2 THROUGH D5 MIRROR IMAGE TO TISSUE PROTOCOL, D5--SECTION OF LESION AND MOST MEDIAL MARGIN, D7--TUMOR (MIRROR IMAGE TO PROTOCOL), D8--UPPER INNER QUADRANT IMMEDIATELY ADJACENT TO TUMOR; D9--UPPER OUTER QUADRANT 7 CM FROM TUMOR, D10--LOWER OUTER QUADRANT 7 CM FROM TUMOR, D11--LOWER INNER QUADRANT 4 CM FROM TUMOR.

PROCEDURES:

88307/4, IMMUNOPEROXIDAS/2, A BLK/10, BBX X6, CBX X6, D BLK/11

PART A LEFT BREAST, SIMPLE MASTECTOMY: DIFFUSE FIBROCYSTIC CHANGES WITH ADENOSIS AND FOCALLY MARKED NON-ATYPICAL INTRADUCTAL EPITHELIAL HYPERPLASIA PRESENT. NO EVIDENCE OF MALIGNANCY.

FCC
Adenosis, was
nonatyp IDH-2

PART B RIGHT AXILLARY SENTINEL LYMPH NODE #1: REACTIVE LYMPH NODE WITH NO EVIDENCE OF METASTATIC DISEASE, SUPPORTED BY NEGATIVE CYTOKERATIN IMMUNOHISTOCHEMICAL STAINING.

9/

PART C RIGHT AXILLARY SENTINEL LYMPH NODE #2: ISOLATED TUMOR CELL CLUSTER, 0.1 MM, IDENTIFIED IN A CAPSULAR LYMPHATIC SPACE. THE LESION IS VISIBLE ON ROUTINE H&E STAINING, CONFIRMED BY POSITIVE CYTOKERATIN IMMUNOHISTOCHEMICAL STAINING. THE FOCUS DISAPPEARS ON DEEPER SECTIONING INTO THE TISSUE BLOCK.

1/1 isol. cell
0.1mm

PART D RIGHT SIMPLE MASTECTOMY: MODERATELY DIFFERENTIATED INFILTRATING DUCTAL CARCINOMA, NUCLEAR GRADE III/III WITH A HIGH MITOTIC INDEX WITH INVASIVE CARCINOMA SPANNING A MICROSCOPIC DISTANCE OF 2.6 CM. MINOR FOCI OF MICROPAPILLARY-TYPE DUCTAL CARCINOMA IN SITU ARE PRESENT, BUT OVER 90% OF THE TUMOR IS INVASIVE. THE TUMOR IS LOCATED IN THE UPPER INNER QUADRANT OF THE BREAST (2 O'CLOCK POSITION) WITH A MICROSCOPIC TENDRIL OF TUMOR EXTENDING TO THE SUPERFICIAL MARGIN (SLIDE D3). THE MEDIAL MARGIN IS FREE OF TUMOR BY A DISTANCE OF 5 MM AND THE DEEP MARGIN BY APPROXIMATELY 1 CM. REPRESENTATIVE SECTIONS OF BREAST TISSUE AWAY FROM THE PRIMARY TUMOR SITE SHOW PROLIFERATIVE FIBROCYSTIC CHANGES WITH AREAS OF MARKED INTRADUCTAL EPITHELIAL HYPERPLASIA PRESENT, BUT NO ADDITIONAL AREAS OF MALIGNANCY.

IDC 2.6cm
2/3/3

gr. 2
DCIS 69%
micropap

(+) SF margin focal

FCC
IDH-3

[page 3 of 3]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status: [REDACTED]

Spec Type: SURGICAL P

Subm Dr: [REDACTED]

1

Signed _____

(prelim.)

_____(signature on file)_____

Source: NCI Genomic Data Commons file aeac7257-5f42-4882-9ab4-47012279b458 (TCGA-A2-A0T7.383EC600-FBF3-4F91-8FAC-41E3DDE6589E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).